Surgical pathology report (de-identified scan), TCGA case TCGA-94-7033, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - Emory, specimen TCGA-94-7033-01A (Primary Tumor).

[page 1 of 5]
[REDACTED]

This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of [REDACTED] regarding patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

AP Report

[REDACTED]

* Final Report *

Document Type:
Document Date:
Document Status:
Document Title:
Encounter info:

[REDACTED]

* Final Report *

[REDACTED]

SUPPLEMENTAL REPORT

SUPPLEMENTAL DIAGNOSIS:

The diagnosis remains unchanged.

[REDACTED]

COMMENT:

Stains for acid fast bacilli and fungus have been performed on a sclerotic granuloma, and both of these stains are negative.

[REDACTED]

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

1. LUNG, POSTERIOR RIGHT UPPER LOBE AND SUPERIOR SEGMENT RIGHT LOWER LOBE, RESECTION, FS1A, TP1A:
- SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED (6.5 X 4.6 X 3.7 CM).
- LYMPHOVASCULAR AND PERINEURAL INVASION ARE NOT IDENTIFIED.
- SEE SYNOPSIS REPORT.
- SEE COMMENT.
2. #8 LYMPH NODE, EXCISION:
- [REDACTED]

[page 2 of 5]
AP Report

* Final Report *

- REMOTE GRANULOMAS WITH CALCIFICATION.
- NO RESIDUAL LYMPH NODE TISSUE IDENTIFIED.
- NO NEOPLASTIC TISSUE IDENTIFIED.
3. #9 LYMPH NODE:
- ONE LYMPH NODE NEGATIVE FOR METASTATIC CARCINOMA (0/1).
4. 10R LYMPH NODE, EXCISION:
- ONE LYMPH NODE NEGATIVE FOR METASTATIC CARCINOMA (0/1).
- REMOTE GRANULOMAS WITH CALCIFICATION.
5. 11R LYMPH NODE, EXCISION:
- FRAGMENTED LYMPH NODE NEGATIVE FOR METASTATIC CARCINOMA (0/1).
- REMOTE GRANULOMAS.
6. 4R LYMPH NODE, EXCISION:
- FRAGMENTED LYMPH NODE NEGATIVE FOR METASTATIC CARCINOMA (0/1).
- REMOTE GRANULOMAS WITH CALCIFICATION.
7. #7 LYMPH NODE, EXCISION:
- ONE LYMPH NODE NEGATIVE FOR METASTATIC CARCINOMA (0/1).
- REMOTE GRANULOMAS WITH CALCIFICATION AND OSSIFICATION.
8. LUNG, RIGHT UPPER LOBE AND SUPERIOR SEGMENT, RIGHT LOWER LOBE, COMPLETION LOBECTOMY:
- RESIDUAL CARCINOMA WITHIN PERIBRONCHIAL FAT.
- BRONCHOVASCULAR MARGINS ARE NEGATIVE FOR CARCINOMA.
- BULLOUS EMPHYSEMATOUS CHANGES OF PERIPHERAL LUNG PARENCHYMA.
- REMOTE GRANULOMAS.
- EIGHT LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/8).

Histologic type : Squamous cell carcinoma

-- AJCC TNM Staging, 7th Edition, [REDACTED]

Page 1 (Continued...)

Patient: [REDACTED]
Patient Number: [REDACTED]

Accession Number: [REDACTED]

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

Primary tumor (pT) extent : pT2b Tumor more than 5 cm, but 7 cm or less in

[page 3 of 5]
AP Report

* Final Report *

greatest dimension

Tumor size : Maximum tumor diameter : 6.5 cm

Histologic grade : G2 Moderately differentiated

Surgical margins : Bronchial margin: negative
Pulmonary artery margin: negative
Pulmonary vein margin: negative

Vascular invasion : Absent

Lymphatic invasion : Absent

Perineural invasion : Absent

Pleural involvement : The visceral pleura are free of involvement;
tumor is less than 0.1 cm from the visceral
pleura [REDACTED].

Extra-pulmonary invasion : No

Lymph Node Summary (pN) : Number examined 13
Number involved 0
pN0 No regional lymph node metastasis

Distant Metastasis (pM) : pMX Cannot be assessed

Non-neoplastic lung : The non-neoplastic lung shows bullous
emphysematous changes and calcified granulomas.

[REDACTED]

COMMENT:

Immunohistochemical stains performed on block 1F are positive in tumor cells for cytokeratin-7 and are negative in tumor cells for both cytokeratin-20 and uroplakin; this supports the likelihood of the primary origin of the squamous carcinoma within the lung. A bladder tumor metastatic to the lung would likely be positive for CK20 and uroplakin.

Stains for AFB and GMS on the granulomas are in preparation.

SPECIMEN:

1. Posterior RUL and superior segment RLL.
2. #8 lymph node.
3. #9 lymph node.

[page 4 of 5]
AP Report

* Final Report *

4. 10R lymph node.
5. 11R L node.
6. 4R L node.
7. #7 L node.
8. Completion RUL and superior segment RLL.

CLINICAL HISTORY/OPERATIVE FINDINGS:

Right VATS with wedge excision. History of bladder cancer. Lung mass (RUL).

GROSS DESCRIPTION:

Parts 2-4 are received fresh for frozen section, each labeled with the patient's name and medical record number.

Specimen #1 is received fresh for intraoperative diagnosis, labeled with the patient's name, medical record number and as "posterior RUL and superior segment RLL." The specimen consists of part of right upper lobe and attached

Page 2 (Continued...)

SURGICAL PATHOLOGY REPORT

GROSS DESCRIPTION:

right lower lobe measuring 17.5 x 7.5 x 3.8 cm. A poorly circumscribed firm subpleural tumor is identified in the specimen measuring 6.5 x 4.6 x 3.7 cm. Dark pigmentation and necrosis are present in the tumor. The tumor abuts the resection margin. The uninvolved right upper lobe is unremarkable. The right lower lobe is emphysematous, and no lesions are identified. A representative section of the tumor in relation to pleura is submitted for frozen section diagnosis in cassette "FS1A." The pleura is inked black and the resection margin is inked blue. In addition a scrape (touch prep) of the tumor is submitted for intraoperative diagnosis. Additional sections are submitted as stated below.

Part #2 is labeled "#8 lymph node" and consists of a fatty and calcified, possible lymph node measuring 1.3 x 0.8 x 0.7 cm. Specimen cannot be cut and therefore no frozen section is done. Specimen is bisected and submitted entirely in cassette "2A" after decalcification.

Specimen #3 is labeled "#9 lymph node" and consists of a fatty, possible lymph node measuring 0.6 x 0.4 x 0.2 cm. The specimen is entirely submitted for

[page 5 of 5]
AP Report

* Final Report *

Medical Laboratory is certified under the Clinical Laboratory Improvement Amendments (CLIA) as qualified to perform high complexity clinical laboratory testing.

The pathologist has reviewed and interpreted the case with the resident/fellow.

SPECIAL STAINS:

AFB	DONE
GMS	DONE
CYTO7	DONE
CYTO20	DONE
UROPLAKIN	DONE

Medical Records

Page 4 (End of Report)

Source: NCI Genomic Data Commons file 3564c56f-90cc-4f93-90a6-de1a323eb5c5 (TCGA-94-7033.A35D486D-6DDD-4E45-999C-3C66496DA495.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).